EXCEPTIONAL_RESPONDERS case ER-AFDK — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d367f9d4-fa2b-4ccd-8b7d-9ac8ba3c0599

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1930; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 81.4 years (29,734 days); Year of diagnosis: 2011; AJCC staging edition: 7th; Prior malignancy: no; Days to last follow up: 1,912 days (5.2 years); Days to best overall response: 90 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: 45 days; Days to treatment end: 76 days.

Follow-up (1 entry)
- Days to follow up: 1,912 days (5.2 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,912 days (5.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AFDK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AFDK-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 55; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
